Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017975-03A.1 (aliquot TARGET-15-SJMPAL017975-03A.1-01D) from TARGET case TARGET-15-SJMPAL017975, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,527 days).
Specimen TARGET-15-SJMPAL017975-03A.1: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d4ddb79-9a39-48cd-a831-873c7be1d38f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017975-10A.1 (Blood Derived Normal), aliquot TARGET-15-SJMPAL017975-10A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ec16901-f24e-4606-b7f5-c5a8eb3e7337

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Splice Site 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 49/171 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909646, COSV54042199, COSV54043241, COSV54057031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JADE2 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs767660256; called by muse, varscan2
- SEMA3B | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1357491950; called by muse, mutect2
- SMC5 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs369127149; called by muse, mutect2
- CDC42 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2
- DIP2B | c.3981+1G>A p.X1327_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- DNAH7 | c.2595G>T p.L865F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2
- MN1 | c.3725_3732dup p.L1245Tfs*78 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- OBSCN | c.10617G>T p.R3539S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PTPRB | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SMCHD1 | c.4432C>A p.Q1478K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TUBGCP3 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- BAZ1A | c.744G>T p.T248= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV62411892; called by muse, mutect2
- TXNIP | c.99G>T p.V33= | Silent (SNP) | VAF 64/126 reads (51%) | called by muse, varscan2
- ADGRE4P | n.2541G>T | RNA (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+5505G>T | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
